Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A11A, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A11A-01A (Primary Tumor).

[page 1 of 4]
1CD-0-3

Carcinoma, hepatocellular, NOS 8170/3

Site: liver c22.0 1/24/11 lw

Patient Key.
Surgical date:

TISSUE DESCRIPTION:

3 A1 A2 B1 B2 B3 B4 B5 B6 B7 B8 B9 B10 B11 C1 D1 E1 E2
Left lobe of liver (1425.0 grams, 17.0 x 14.0 x 11.0 cm),
gallbladder (8.5 x 1.2 cm) and, separately submitted, common hepatic
artery, supra-duodenal and retro choledochal lymph nodes

DIAGNOSIS:

Liver, left lobe, partial hepatectomy: Grade 3 (of 4)
hepatocellular carcinoma is identified forming a single encapsulated
14.0 x 10.0 x 8.0 cm well-circumscribed tumor confined to the liver.
The margins of resection are negative for tumor (tumor free margin
is 3.0 cm). Extra-tumoral vascular invasion is not identified. The
non-neoplastic liver will be evaluated and reported in an addendum.

Gallbladder, cholecystectomy: Acute and chronic serositis. No gall
stones are identified.

Lymph nodes, common hepatic artery and retro choledochal, excisions:
Multiple (2 common hepatic artery and 1 retro choledochal) lymph
nodes are negative for tumor, both specimens.

Soft tissue, supra duodenal region, excision: Tissue submitted as
supra duodenal lymph node shows benign fibroadipose tissue. No
lymph node is identified.

Review for Trials		

lw

[page 2 of 4]
1CD-0-3

Carcinoma, hepatocellular, NOS 8170/3

Site: liver c22.0 1/24/11 lw

Patient Key:
Surgical date:

TISSUE DESCRIPTION:

, A1 A2 B1 B2 B3 B4 B5 B6 B7 B8 B9 B10 B11 C1 D1 E1 E2
Left lobe of liver (1425.0 grams, 17.0 x 14.0 x 11.0 cm),
gallbladder (8.5 x 1.2 cm) and, separately submitted, common hepatic
artery, supra-duodenal and retro choledochal lymph nodes

DIAGNOSIS:

Liver, left lobe, partial hepatectomy: Grade 3 (of 4)
hepatocellular carcinoma is identified forming a single encapsulated
14.0 x 10.0 x 8.0 cm well-circumscribed tumor confined to the liver.

The margins of resection are negative for tumor (tumor free margin
is 3.0 cm). Extra-tumoral vascular invasion is not identified. The
non-neoplastic liver will be evaluated and reported in an addendum.

Gallbladder, cholecystectomy: Acute and chronic serositis. No gall
stones are identified.

Lymph nodes, common hepatic artery and retro choledochal, excisions:
Multiple (2 common hepatic artery and 1 retro choledochal) lymph
nodes are negative for tumor, both specimens.

Soft tissue, supra duodenal region, excision: Tissue submitted as
supra duodenal lymph node shows benign fibroadipose tissue. No
lymph node is identified.

[page 3 of 4]
Liver - Digestive System CAP Approved

* Data elements *with asterisks* are *not required* for accreditation purposes for the Commission on Cancer. These elements may be clinically important, but are not yet validated or regularly used in patient management. Alternatively, the necessary data may not be available to the pathologist at the time of pathologic assessment of this specimen.

LIVER: Resection

Patient name: *(to be de-identified)* Patient Key:

Surgical pathology number:

Surgery Date:

MACROSCOPIC

Specimen Type

- ☐ Right lobectomy
- ☐ Extended right lobectomy
- ☐ Medial segmentectomy
- ☒ Left lateral segmentectomy
- ☐ Total left lobectomy
- ☐ Explanted liver
- ☐ Other (specify): _____
- ☐ Not specified

Focality

- ☒ Solitary (specify location): left lobe
- ☐ Multiple (specify location): _____

Tumor Size

Greatest dimension: 14.0 cm

*Additional dimensions: 10.0 x 8.0 cm

☐ Cannot be determined (see Comment)

MICROSCOPIC

Histologic Type

- ☒ Hepatocellular carcinoma
- ☐ Fibrolamellar hepatocellular carcinoma variant (specify): _____
- ☐ Combined hepatocellular and cholangiocarcinoma
- ☐ Cholangiocarcinoma, intrahepatic
- ☐ Bile duct cystadenocarcinoma
- ☐ Undifferentiated carcinoma
- ☐ Other (specify): _____
- ☐ Carcinoma, type cannot be determined

Histologic Grade

- ☐ Not applicable
- ☐ GX: Cannot be assessed
- ☐ GI: Well differentiated
- ☐ GII: Moderately differentiated
- ☒ GIII: Poorly differentiated
- ☐ GIV: Undifferentiated/anaplastic
- ☐ Other (specify): _____

[page 4 of 4]
Pathologic Staging (pTNM)

Primary Tumor (pT)

- ☐ pTX: Cannot be assessed
☒ pT0: No evidence of primary tumor
☒ pT1: Solitary tumor with no vascular invasion
☐ pT2: Solitary tumor with vascular invasion or multiple tumors none more than 5 cm
☐ pT3: Multiple tumors more than 5 cm or tumor involving a major branch of the portal or hepatic vein(s)
☐ pT4: Tumor(s) with direct invasion of adjacent organs other than the gallbladder or perforation of visceral peritoneum

Regional Lymph Nodes (pN)

- ☒ pNX: Cannot be assessed
☒ pN0: No regional lymph node metastasis
☐ pN1: Regional lymph node metastasis

Specify: Number examined: 3

Number involved: 0

Distant Metastasis (pM)

- ☒ pMX: Cannot be assessed
☐ pM1: Distant metastasis

*Specify site(s), if known: _____

Margins (check all that apply)

Parenchymal Margin

- ☐ Cannot be assessed
☒ Uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 30.0 mm
Specify margin: _____

☐ Involved by invasive carcinoma

Bile Duct Margin (Cholangiocarcinoma Only)

- ☐ Cannot be assessed
☐ Uninvolved by invasive carcinoma
☐ Carcinoma in situ absent
☐ Carcinoma in situ present
☐ Involved by invasive carcinoma

Other Margin

Specify margin: _____

- ☐ Cannot be assessed
☐ Uninvolved by invasive carcinoma
☐ Involved by invasive carcinoma

***Venous (Large Vessel) Invasion (V)**

- * ☐ Absent
* ☐ Present
* ☒ Indeterminate

***Additional Pathologic Findings (check all that apply)**

- * ☒ None identified
* ☐ Hepatocellular dysplasia
* ☐ Ductal dysplasia
* ☐ Cirrhosis/fibrosis
* ☐ Iron overload
* ☐ Hepatitis (specify type): _____
* ☐ Other (specify): _____

Source: NCI Genomic Data Commons file 43542cd1-7697-482e-b9b6-593c6d36d74b (TCGA-DD-A11A.E1571DB1-B1B2-4B0E-9A0A-01A4470353DF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).